CPTAC case C3N-02000 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61ca5e2a-1809-4970-a50f-07698816ef85

Demographics
Sex at birth: female; Race: asian; Year of birth: 1971; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 46.3 years (16,924 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,703 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,703 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 6 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 14; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 346 days; Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 687 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,086 days (3.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,086 days (3.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,345 days (3.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,703 days (4.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 63 kg; Height: 162 cm; BMI: 24.01; DLCO (% of predicted): 93.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02000-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02000-21: Section location: Right Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 3.
- Sample C3N-02000-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02000-23: Section location: Right Lower Lobe; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample C3N-02000-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 60 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-02000-31, C3N-02000-32, C3N-02000-72, C3N-02000-73, C3N-02000-74 (5 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02000-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
